Somatic mutation profile of tumor specimen TCGA-F1-A448-01A (aliquot TCGA-F1-A448-01A-11D-A24D-08) from TCGA case TCGA-F1-A448, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 70.8 years (25,846 days).
Specimen TCGA-F1-A448-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b7d34d5-03a9-41a7-b02c-78da99f13305.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F1-A448-10A (Blood Derived Normal), aliquot TCGA-F1-A448-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae79789d-2a05-4316-b3e8-349af9b59116

The open-access MAF lists 564 somatic variants for this specimen: 434 protein-altering or splice-affecting, 117 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 299, Silent 117, Frame Shift Del 87, Frame Shift Ins 14, Nonsense Mutation 13, In Frame Del 10, Splice Site 8, Intron 7, 3'UTR 2, RNA 2, Splice Region 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 12/83 reads (14%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 15/164 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.1940dup p.P648Tfs*2 | Frame Shift Ins (INS) | VAF 14/61 reads (23%) | catalogued as rs770315135; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RHOA | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 11/99 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs11552761, COSV69041529, COSV69041693, COSV69041915, COSV69043569; called by muse, mutect2, varscan2
- TNNT2 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516456, CM971501, COSV52663578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel
- ABCB1 | c.2576T>G p.L859R | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55954941; called by muse, mutect2, varscan2
- ABCC9 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs886039121, COSV53976492; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD16A | c.1298T>C p.I433T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs751774399, COSV65452023; called by muse, mutect2
- ACOT6 | c.281T>G p.L94R | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV66969045; called by muse, mutect2, varscan2
- ACSM5 | c.983T>C p.V328A | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV59372792; called by muse, mutect2
- ACTL8 | c.290del p.P97Lfs*2 | Frame Shift Del (DEL) | VAF 8/79 reads (10%) | catalogued as rs1557449414; called by pindel, varscan2
- ACTL8 | c.305A>T p.E102V | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV64861841; called by muse, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 36/110 reads (33%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAD1 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as COSV56644668, COSV99635370; called by muse, mutect2, varscan2
- ADAM28 | c.1213A>G p.I405V | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs1295379523, COSV56102004; called by muse, mutect2
- ADAMTS16 | c.2225A>C p.N742T | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV56995027; called by muse, mutect2, varscan2
- ADCY3 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1190233494, COSV53169160; called by muse, mutect2, varscan2
- ADHFE1 | c.61T>C p.C21R | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV52556645; called by muse, mutect2, varscan2
- ADORA1 | c.47A>G p.E16G | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58811279; called by muse, mutect2
- ALK | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs745712273, COSV66574662; ClinVar: uncertain significance; called by muse, mutect2
- AMELY | c.344T>C p.L115P (on ENST00000383036 / NM_001364814.1; = p.L101P on NM_001143.1) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV53095891; called by muse, mutect2, varscan2
- ANAPC2 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs372127262, COSV60570714; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | catalogued as rs34047276; called by mutect2, varscan2
- AP1M1 | c.538A>G p.N180D | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.308); catalogued as COSV52227307; called by muse, mutect2, varscan2
- APBA1 | c.604G>T p.G202W | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV99595685; called by muse, mutect2, varscan2
- APP | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs202074408, COSV60996485, COSV61000372; called by mutect2, varscan2
- ARFGEF1 | c.869G>C p.S290T | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV51611424; called by muse, mutect2
- ARL5A | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV54470669; called by muse, mutect2, varscan2
- ARVCF | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.707); catalogued as rs1331717847, COSV54267834; called by muse, mutect2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs747570359; called by mutect2, varscan2
- ASH1L | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 31/148 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as rs756914885, COSV64209843; called by muse, mutect2, varscan2
- ATG4D | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as rs1401127662, COSV57265064; called by muse, mutect2, varscan2
- ATL1 | c.903T>G p.I301M | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); catalogued as COSV63296786; called by muse, mutect2
- ATP2A1 | c.2701C>A p.L901M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as COSV100707074, COSV62869796; called by muse, mutect2, varscan2
- ATXN3L | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV66075889; called by mutect2, varscan2
- BCL6B | c.546dup p.S183Qfs*6 | Frame Shift Ins (INS) | VAF 17/150 reads (11%) | catalogued as rs780109291; called by mutect2, varscan2
- BCL9L | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs372773894; called by muse, mutect2, varscan2
- BCOR | c.2932A>T p.K978* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV60710942; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | catalogued as rs772920507, COSV65808737; called by pindel, varscan2
- BRAF | c.1822C>G p.H608D (on ENST00000288602 / NM_001374244.1; = p.H568D on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV56241933; called by muse, mutect2, varscan2
- BRWD1 | c.6542C>T p.T2181M | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs148068634; called by muse, mutect2, varscan2
- BSN | c.10670A>C p.E3557A | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.679); catalogued as COSV56521497; called by muse, mutect2
- BTN2A2 | c.952+1G>A p.X318_splice | Splice Site (SNP) | VAF 30/122 reads (25%) | catalogued as rs200463511, COSV61856950, COSV61857844; called by muse, mutect2
- BUB1 | c.1660G>A p.G554R | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.589); catalogued as COSV57064849; called by muse, mutect2
- C16orf70 | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs761426908, COSV54627900; called by muse, mutect2, varscan2
- C17orf80 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs200611765; called by muse, mutect2, varscan2
- CACNA1D | c.766A>G p.S256G | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV55453197; called by muse, mutect2
- CACNA2D3 | c.2185G>A p.G729S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1395948016, COSV55552740; called by muse, mutect2
- CADM2 | c.1091G>A p.G364D (on ENST00000407528 / NM_001167674.2; = p.G366D on NM_153184.4) | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV67384408, COSV67407363; called by muse, mutect2
- CADM3 | c.704C>T p.A235V (on ENST00000368125 / NM_001127173.3; = p.A269V on NM_021189.5) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs778876352, COSV63686096; called by muse, mutect2, varscan2
- CAPN5 | c.920G>A p.G307D (on ENST00000456580; = p.G267D on NM_004055.5) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as COSV53689230; called by muse, mutect2, varscan2
- CARM1 | c.1675A>G p.I559V | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.024); catalogued as COSV53404210; called by muse, mutect2, varscan2
- CARNMT1 | c.1097del p.N366Tfs*10 | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | catalogued as rs769078744; called by mutect2, pindel, varscan2
- CCAR2 | c.2447T>C p.L816P | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52385255; called by muse, mutect2
- CCDC170 | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs770534076, COSV53342478; called by mutect2, varscan2
- CCDC171 | c.3806C>T p.P1269L | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.022); catalogued as COSV66239162, COSV66241270; called by muse, mutect2
- CCDC85A | c.919A>T p.K307* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as COSV68152638; called by muse, mutect2, varscan2
- CCDC9B | c.609dup p.T204Hfs*56 | Frame Shift Ins (INS) | VAF 12/91 reads (13%) | catalogued as rs772754432; called by mutect2, varscan2
- CCN3 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52384328; called by muse, mutect2
- CD22 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.161); catalogued as rs756111081, COSV50056700; called by mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CDH2 | c.1084C>A p.L362I | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52285168; called by muse, mutect2, varscan2
- CDHR5 | c.1865C>A p.P622H (on ENST00000358353 / NM_001171968.2; = p.P628H on NM_021924.5) | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1246622051, COSV57644176; called by muse, mutect2, varscan2
- CDK10 | c.874C>G p.L292V (on ENST00000353379 / NM_052988.5; = p.L221V on NM_052987.4) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.38); catalogued as COSV57047535; called by muse, mutect2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs1325731082; called by mutect2, pindel
- CEP162 | c.2890T>A p.F964I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1562021263, COSV57621193; called by muse, mutect2
- CEP55 | c.1310T>C p.L437P | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV65185350; called by muse, mutect2, varscan2
- CES2 | c.872G>A p.C291Y | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57697198; called by muse, mutect2, varscan2
- CFH | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV62777358; called by muse, mutect2, varscan2
- CHD1L | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs368838337; ClinVar: uncertain significance; called by muse, mutect2
- CHD2 | c.4969T>C p.W1657R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV67711029; called by muse, mutect2, varscan2
- CHD5 | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs767762669, COSV52415643; called by mutect2, varscan2
- CHD7 | c.1351G>A p.G451S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated, low confidence (0.52); PolyPhen possibly damaging (0.762); catalogued as rs1475943467, COSV71112277; called by muse, mutect2, varscan2
- CHRM2 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.141); catalogued as rs1486838543, COSV57776114; called by muse, mutect2, varscan2
- CKAP5 | c.3029G>A p.R1010H | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56369759; called by muse, mutect2, varscan2
- CNTNAP2 | c.1663A>G p.I555V | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as COSV62207516; called by muse, mutect2
- COL12A1 | c.7438G>A p.V2480M | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs183898615, COSV59399310; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL22A1 | c.4192C>T p.P1398S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.299); catalogued as COSV57345091; called by muse, mutect2
- COL27A1 | c.2335G>A p.V779I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs775130773, COSV61927805; called by mutect2, varscan2
- COL6A6 | c.3535G>A p.A1179T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV62025173, COSV62029068; called by muse, mutect2
- COPS5 | c.941C>A p.A314D | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.258); catalogued as COSV100769909; called by muse, mutect2
- CPEB2 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as rs1162407034, COSV52592867; called by muse, mutect2
- CRACD | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51714224, COSV51735460; called by muse, mutect2
- CRELD1 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as rs774018674, COSV55976321; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRLF2 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs745525402, COSV67493885; called by muse, mutect2
- CRX | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs142111462, COSV55759068; called by muse, mutect2, varscan2
- CSMD3 | c.5044G>T p.G1682* (on ENST00000297405 / NM_001363185.1; = p.G1578* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 6/87 reads (7%) | catalogued as COSV52223034; called by muse, mutect2
- CSNK1A1L | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV65789854; called by muse, mutect2
- CUX1 | c.44C>T p.A15V (on ENST00000292535 / NM_181552.4; = p.A26V on NM_001913.5) | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV52904453, COSV99471013; called by muse, mutect2
- CYP1A1 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.086); catalogued as COSV65697574; called by muse, mutect2, varscan2
- DAO | c.772A>G p.T258A | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.02); catalogued as COSV57323170; called by muse, mutect2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DBR1 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.084); catalogued as rs1467610282, COSV53430304; called by muse, mutect2, varscan2
- DCAF12L1 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1180607542, COSV64422079; called by muse, mutect2
- DCAF12L2 | c.1249T>C p.W417R | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV63582551; called by muse, mutect2, varscan2
- DDHD1 | c.646C>T p.H216Y (on ENST00000323669; = p.H413Y on NM_030637.3) | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100079252; called by muse, mutect2
- DIS3L2 | c.2125G>A p.V709I | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0.062); catalogued as rs199537907; called by muse, mutect2, varscan2
- DLGAP2 | c.2317G>A p.V773I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs34274599, COSV70097003; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAH9 | c.1756A>G p.S586G | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV52357597; called by muse, mutect2
- DNAH9 | c.9617G>A p.R3206Q | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs758199662, COSV52357604; called by muse, mutect2, varscan2
- DNM3 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as COSV62461276; called by muse, mutect2
- DQX1 | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 13/144 reads (9%) | catalogued as rs150420269; called by muse, mutect2
- DSCAM | c.5628del p.K1877Nfs*8 | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | catalogued as rs766229789; called by mutect2, pindel, varscan2
- DUS1L | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57649750; called by muse, mutect2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | catalogued as rs746928635; called by mutect2, pindel, varscan2
- ECEL1 | c.1886G>T p.G629V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100458549; called by muse, mutect2, varscan2
- EFCAB1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs753689165, COSV50617909; called by muse, mutect2
- EFNA5 | c.286G>T p.G96W | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60953045; called by muse, mutect2, varscan2
- EHBP1L1 | c.4185T>C p.G1395= | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as COSV58573775; called by muse, mutect2
- EHMT1 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1431569163, COSV58377180; called by muse, mutect2
- EIF2AK4 | c.2567del p.L856Wfs*7 | Frame Shift Del (DEL) | VAF 14/166 reads (8%) | catalogued as rs35250897; called by mutect2, pindel
- EIF4G1 | c.2167G>A p.E723K (on ENST00000346169 / NM_198241.3; = p.E528K on NM_004953.5) | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs770352096, COSV59990025; called by muse, mutect2, varscan2
- EIF4G3 | c.421del p.T141Lfs*2 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs1290746509; called by mutect2, pindel
- ELP3 | c.1100+2T>C p.X367_splice | Splice Site (SNP) | VAF 5/32 reads (16%) | catalogued as COSV56459968; called by muse, mutect2, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 9/100 reads (9%) | catalogued as rs759858342; called by mutect2, pindel
- EN2 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52083392; called by muse, mutect2
- ENGASE | c.1751G>A p.C584Y | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.129); catalogued as COSV56136311; called by muse, mutect2, varscan2
- EPHX2 | c.842T>A p.L281Q | Missense Mutation (SNP) | VAF 47/352 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100994433, COSV66845288; called by muse, mutect2, varscan2
- ESYT1 | c.984+2T>C p.X328_splice | Splice Site (SNP) | VAF 10/84 reads (12%) | catalogued as COSV57274415; called by muse, mutect2, varscan2
- EXOC2 | c.25dup p.L9Pfs*9 | Frame Shift Ins (INS) | VAF 14/105 reads (13%) | catalogued as rs748159069; called by mutect2, varscan2
- FAM189A2 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as COSV57385107; called by muse, varscan2
- FAM83G | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV58759545; called by muse, mutect2
- FARP2 | c.1604A>G p.E535G | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV50873600; called by muse, mutect2
- FBXO47 | c.1076del p.L359Wfs*18 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | catalogued as rs34478092; called by mutect2, pindel, varscan2
- FCN2 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.357); catalogued as COSV52477543; called by muse, mutect2, varscan2
- FEN1 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1565315915, COSV57251047; called by muse, mutect2, varscan2
- FERMT1 | c.1973A>G p.K658R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.677); catalogued as COSV54094541; called by muse, mutect2, varscan2
- FGD5 | c.1880A>C p.K627T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV53245994; called by muse, mutect2, varscan2
- FGD5 | c.2285G>T p.R762L | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53246023; called by muse, mutect2
- FGF19 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV53736630; called by muse, mutect2, varscan2
- FHDC1 | c.2112G>T p.M704I | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV99471122; called by muse, mutect2
- FILIP1 | c.3023A>G p.Q1008R | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.652); catalogued as COSV52733885; called by muse, mutect2
- FLOT1 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270336618, COSV52544173; called by muse, mutect2
- FNDC11 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as rs200982478; called by muse, mutect2
- FRMPD1 | c.2426C>A p.P809H | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.258); catalogued as COSV66700949; called by muse, mutect2
- FUCA2 | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 7/89 reads (8%) | catalogued as rs1034334965, COSV50019785; called by muse, mutect2
- FUT6 | c.407T>C p.M136T | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV54606689; called by muse, mutect2
- G6PD | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV63703586; called by muse, mutect2, varscan2
- GADL1 | c.1457A>G p.H486R | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.179); catalogued as rs1004139181, COSV56980965; called by muse, mutect2
- GART | c.1675T>C p.C559R | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63113982; called by muse, mutect2, varscan2
- GCLM | c.790G>T p.G264C | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64687213; called by muse, mutect2
- GCNA | c.438_467del p.E177_S186del | In Frame Del (DEL) | VAF 15/135 reads (11%) | catalogued as rs776487083; called by muse*, mutect2
- GDPD1 | c.387A>C p.K129N | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV52382521; called by muse, mutect2, varscan2
- GDPGP1 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs143661647, COSV61575812; called by muse, varscan2
- GOLGA1 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs780458941, COSV63024194; called by muse, mutect2, varscan2
- GPR158 | c.3155C>A p.P1052H | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV66273974; called by muse, mutect2, varscan2
- GPR162 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as rs201727451, COSV50592224; called by muse, mutect2
- GPT | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 29/338 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as COSV52953655; called by muse, mutect2
- GPX5 | c.188A>T p.H63L | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as COSV69079583; called by muse, mutect2
- GRK2 | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.018); catalogued as rs1440574399, COSV100398656; called by muse, mutect2
- GUCY1A1 | c.2048del p.L683* | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | catalogued as rs751481702, COSV56650103, COSV56656519; called by mutect2, pindel
- HAVCR1 | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 32/511 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.38); catalogued as COSV59400934; called by muse, mutect2
- HDAC3 | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV59496236; called by muse, mutect2
- HECTD3 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs765075487, COSV55800953; called by muse, mutect2, varscan2
- HEY2 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV64240160; called by muse, mutect2
- HEY2 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 22/287 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV64239832; called by muse, mutect2
- HOOK3 | c.1233C>T p.D411= | Splice Region (SNP) | VAF 6/32 reads (19%) | catalogued as rs188582867, COSV56882933; called by muse, mutect2, varscan2
- HSD3B7 | c.543del p.L182Cfs*4 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | catalogued as COSV52682172; called by mutect2, pindel
- HSPA1A | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100989356; called by muse, mutect2, varscan2
- HTR1E | c.801del p.F268Sfs*5 | Frame Shift Del (DEL) | VAF 17/176 reads (10%) | catalogued as rs753568078, COSV59508996, COSV59509296; called by mutect2, pindel
- IGSF10 | c.4947G>T p.R1649S | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV56787155; called by muse, mutect2
- INPPL1 | c.2489G>A p.G830D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53356780; called by muse, mutect2, varscan2
- INSL5 | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as rs1220233937, COSV58788327; called by muse, mutect2, varscan2
- INSYN2A | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755325636, COSV54741977; called by muse, mutect2, varscan2
- IPO9 | c.595A>G p.M199V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.049); catalogued as rs772463340, COSV64234208; called by muse, mutect2, varscan2
- IQCE | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.024); catalogued as rs546809382, COSV58078512; called by muse, mutect2, varscan2
- ITGB2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs148775158; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITIH1 | c.2401C>T p.R801* | Nonsense Mutation (SNP) | VAF 15/185 reads (8%) | catalogued as rs200827836; called by muse, mutect2
- KCNA5 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1273507819, COSV52906336; called by muse, mutect2, varscan2
- KCNC4 | c.26_28del p.S9del | In Frame Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs748484156; called by pindel, varscan2
- KCNU1 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs747155579, COSV67757404; called by mutect2, varscan2
- KDM2B | c.3943A>G p.I1315V | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV65642446; called by muse, mutect2, varscan2
- KDM3A | c.1333T>C p.S445P | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV57222453; called by muse, mutect2, varscan2
- KDM4D | c.278del p.K93Rfs*4 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | catalogued as rs142280183; called by mutect2, varscan2
- KIAA1109 | c.2906G>A p.R969Q | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.968); catalogued as rs369532932; called by muse, mutect2, varscan2
- KIDINS220 | c.603+2T>C p.X201_splice | Splice Site (SNP) | VAF 30/177 reads (17%) | catalogued as COSV56755355; called by muse, mutect2, varscan2
- KIR2DL3 | c.775C>A p.L259I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs796577872, COSV60898569; called by muse, mutect2
- KIR3DL1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs777577843, COSV58492751; called by muse, mutect2
- KLHL14 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV63833672; called by muse, mutect2
- KRI1 | c.1990C>T p.L664F | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV57265069; called by muse, mutect2
- KRT13 | c.962T>C p.I321T | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV55840402; called by muse, mutect2, varscan2
- KRT73 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV59840012, COSV59841410; called by muse, mutect2
- KRT79 | c.1274T>C p.L425P | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57940674; called by muse, mutect2
- LAMC3 | c.1139G>A p.C380Y | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242337882, COSV63092889; called by muse, mutect2, varscan2
- LAYN | c.574G>A p.A192T (on ENST00000375615 / NM_001258390.1; = p.A184T on NM_178834.5) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65105019; called by muse, mutect2, varscan2
- LENG1 | c.346T>C p.Y116H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs753376322, COSV55364926; called by muse, mutect2, varscan2
- LENG8 | c.1948C>A p.L650M | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58728709; called by muse, mutect2
- LIPA | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51079514; called by muse, mutect2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as rs780042765; called by mutect2, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 18/118 reads (15%) | catalogued as rs765287063; called by mutect2, varscan2
- LNPEP | c.41A>C p.N14T | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51478953; called by muse, mutect2
- LSP1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV61135574; called by muse, mutect2
- LURAP1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs529637681, COSV64338283; called by muse, mutect2, varscan2
- LY75-CD302 | c.5134_5136del p.E1712del | In Frame Del (DEL) | VAF 9/54 reads (17%) | catalogued as rs779639279; called by pindel, varscan2
- LYST | c.3393+2T>C p.X1131_splice | Splice Site (SNP) | VAF 9/36 reads (25%) | catalogued as COSV67708905; called by muse, mutect2, varscan2
- MACF1 | c.19944G>T p.E6648D (on ENST00000372915; = p.E4693D on NM_012090.5) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as COSV57128807; called by muse, mutect2, varscan2
- MB21D2 | c.1371del p.K457Nfs*5 | Frame Shift Del (DEL) | VAF 12/126 reads (10%) | catalogued as rs34835215; called by mutect2, pindel
- MBNL1 | c.174+1G>C p.X58_splice | Splice Site (SNP) | VAF 7/64 reads (11%) | catalogued as COSV56831142; called by muse, mutect2
- MDN1 | c.7297G>T p.G2433* | Nonsense Mutation (SNP) | VAF 10/97 reads (10%) | catalogued as COSV65524035; called by muse, mutect2, varscan2
- MED12L | c.1011dup p.G338Rfs*28 | Frame Shift Ins (INS) | VAF 35/170 reads (21%) | catalogued as rs772983071; called by mutect2, varscan2
- MGA | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54952525, COSV54957051; called by muse, mutect2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | catalogued as rs750307488; called by mutect2, varscan2
- MSH6 | c.3028A>G p.T1010A | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV52282111; called by muse, mutect2, varscan2
- MTERF3 | c.1246del p.T416Rfs*15 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as rs1563542774; called by mutect2, pindel
- MTERF3 | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV54633335; called by muse, mutect2
- MYO1E | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1036473071, COSV55689971; called by muse, mutect2, varscan2
- NALCN | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.88); catalogued as rs1253661312, COSV51945311; called by muse, mutect2
- NAPRT | c.980A>G p.Q327R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV52786612; called by muse, mutect2, varscan2
- NCK2 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.177); catalogued as rs766256305, COSV51890162; called by mutect2, varscan2
- NDUFV1 | c.437del p.G146Afs*36 | Frame Shift Del (DEL) | VAF 16/149 reads (11%) | catalogued as rs1565224926; called by mutect2, pindel, varscan2
- NEK10 | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV55360926; called by muse, mutect2
- NEK9 | c.2216G>A p.G739D | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as COSV53131846; called by muse, mutect2, varscan2
- NES | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV63961523; called by muse, mutect2
- NHP2 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 31/270 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.631); catalogued as rs768262654, COSV51071066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRC5 | c.3584del p.K1195Rfs*38 | Frame Shift Del (DEL) | VAF 24/200 reads (12%) | catalogued as COSV52649578, COSV99347793; called by mutect2, pindel, varscan2
- NLRP12 | c.1940A>G p.H647R | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV60749721; called by muse, mutect2
- NOTCH1 | c.5885G>A p.R1962H | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1484525055, COSV53061901; called by muse, mutect2
- NR5A2 | c.509C>T p.P170L (on ENST00000367362 / NM_205860.3; = p.P124L on NM_003822.5) | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV52652834; called by muse, mutect2
- NRXN1 | c.1004T>C p.L335P | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58438968; called by muse, mutect2
- NUP50 | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.697); catalogued as COSV61661228; called by muse, mutect2
- NXF1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs1173388631, COSV53674701; called by muse, mutect2, varscan2
- OGDHL | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs766386468, COSV65103295; called by muse, mutect2, varscan2
- OPTC | c.542G>T p.R181M | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV65867615, COSV65868025; called by muse, mutect2, varscan2
- OR13C9 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV52242616; called by muse, mutect2
- OR2AG2 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs1400684688, COSV100643092; called by muse, mutect2, varscan2
- OR4C16 | c.403A>T p.S135C | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV58940425, COSV58941301, COSV58942700; called by muse, mutect2, varscan2
- OR4C6 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.317); catalogued as rs367948844, COSV58603115; called by muse, mutect2, varscan2
- OR5D13 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as rs1449046456, COSV62334254; called by muse, mutect2
- OR5M11 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1417256854, COSV101602025; called by muse, mutect2
- OR6F1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs376953062, COSV57469358; called by muse, mutect2, varscan2
- OR7G2 | c.455G>T p.R152I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs150795037; called by muse, mutect2, varscan2
- PAK6 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs34445577; called by muse, mutect2
- PALD1 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.191); catalogued as COSV54975246; called by muse, mutect2, varscan2
- PAX6 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV53792520; called by muse, mutect2
- PCDH11X | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs777825266, COSV53476341, COSV53478524; called by muse, mutect2, varscan2
- PCDHA10 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as rs782043318, COSV56517732; called by muse, mutect2
- PCDHB11 | c.762T>G p.N254K | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV53380699; called by muse, mutect2, varscan2
- PCDHB5 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); catalogued as rs555300250, COSV50656891; called by muse, mutect2
- PCLO | c.4127A>G p.E1376G | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61644931; called by muse, mutect2, varscan2
- PDCD4 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV54523664; called by muse, mutect2
- PKP1 | c.1363A>G p.M455V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1431831173, COSV55822615; called by muse, mutect2, varscan2
- PLA2R1 | c.4119del p.G1374Afs*32 | Frame Shift Del (DEL) | VAF 14/124 reads (11%) | catalogued as rs746999253; called by mutect2, varscan2
- PLAT | c.857T>C p.L286P | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV54274678, COSV54276419; called by muse, mutect2
- PLCG2 | c.2567A>C p.N856T | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.996); catalogued as COSV63871680; called by muse, mutect2
- PLCH1 | c.2687C>A p.P896H (on ENST00000340059 / NM_001130960.2; = p.P888H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100396023; called by muse, mutect2
- PLCXD1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs142663151, COSV67542052; called by muse, mutect2, varscan2
- PLD1 | c.2804A>C p.E935A | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV60569848; called by muse, mutect2, varscan2
- PLEC | c.10729T>C p.Y3577H (on ENST00000322810 / NM_201380.4; = p.Y3467H on NM_000445.5) | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59653474; called by muse, mutect2, varscan2
- PLEC | c.7079G>A p.R2360H (on ENST00000322810 / NM_201380.4; = p.R2250H on NM_000445.5) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.379); catalogued as rs565225660, COSV59653509; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHH3 | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs371884155; called by muse, mutect2
- POLE | c.4162C>A p.L1388I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57683717; called by muse, mutect2, varscan2
- POLL | c.1574T>C p.M525T | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1258268622, COSV100150117; called by muse, mutect2
- POLR2F | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 20/212 reads (9%) | catalogued as rs763157475, COSV68091678; called by muse, mutect2
- POU6F2 | c.1843A>G p.T615A | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV68875878; called by muse, mutect2, varscan2
- PPP1R13B | c.2422C>A p.Q808K | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV99157980; called by muse, mutect2
- PPP2R1B | c.1201G>T p.D401Y | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV59536236; called by muse, mutect2, varscan2
- PPP2R2B | c.1184T>G p.V395G (on ENST00000394409; = p.V461G on NM_181674.2) | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs778098894, COSV60751353; called by muse, mutect2
- PRKCE | c.1310A>C p.K437T | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60322502; called by muse, mutect2
- PRKCSH | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs759778147, COSV52952285; called by muse, mutect2, varscan2
- PROKR1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV58136931; called by muse, mutect2
- PRPH2 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs370994796; called by muse, mutect2
- PRRC2A | c.5830C>T p.L1944F | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1255619089, COSV52992278; called by muse, mutect2
- PRRT2 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs989894169, COSV54881036; ClinVar: uncertain significance; called by muse, mutect2
- PRUNE2 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as rs752895318, COSV65028221; called by muse, mutect2, varscan2
- PSG6 | c.806C>T p.T269I | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.88); catalogued as COSV51834487; called by muse, mutect2
- PSPC1 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.155); catalogued as rs911349448, COSV58887102; called by muse, mutect2, varscan2
- PTH2R | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV55915519; called by muse, mutect2, varscan2
- PTPN23 | c.4312_4314del p.E1438del | In Frame Del (DEL) | VAF 4/33 reads (12%) | catalogued as rs760387665; called by mutect2, pindel, varscan2
- PTPRM | c.296T>G p.F99C | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59866957; called by muse, mutect2, varscan2
- RBM33 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs771230490, COSV55296581; called by muse, mutect2, varscan2
- RDH10 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV53583126; called by muse, mutect2
- RHD | c.1019A>G p.E340G | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV59646629; called by muse, mutect2
- RIMKLA | c.310A>C p.S104R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV69815561; called by muse, mutect2
- RIN2 | c.1575dup p.I526Hfs*108 (on ENST00000255006 / NM_001242581.1; = p.I477Hfs*108 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 7/61 reads (11%) | catalogued as rs772265832; called by mutect2, pindel, varscan2
- RMDN2 | c.976del p.M326Wfs*39 (on ENST00000354545 / NM_001322212.2; = p.M504Wfs*39 on NM_144713.5) | Frame Shift Del (DEL) | VAF 9/88 reads (10%) | catalogued as rs770517879; called by mutect2, pindel, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL29 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs772176036, COSV53686097; called by muse, mutect2, varscan2
- SCAF11 | c.3941T>C p.M1314T | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV65477417; called by muse, mutect2, varscan2
- SCAP | c.3743G>A p.R1248H | Missense Mutation (SNP) | VAF 20/331 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs185806499, COSV55545716; called by muse, mutect2
- SDF2L1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759307174, COSV50707855, COSV50707879; called by mutect2, varscan2
- SEC16A | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369124445; called by muse, mutect2, varscan2
- SH2B1 | c.1534del p.E512Sfs*31 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | catalogued as rs1410542268; called by mutect2, pindel, varscan2
- SHOC1 | c.848C>T p.T283I | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1205861813, COSV59503565; called by muse, mutect2
- SHQ1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.204); catalogued as rs200631457; called by muse, mutect2, varscan2
- SI | c.1720G>A p.V574I | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs1344831003, COSV52285676; called by muse, mutect2
- SIGLEC5 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.411); catalogued as rs767883806, COSV55778604, COSV55779752; called by muse, mutect2, varscan2
- SLAIN2 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376159324; called by muse, mutect2, varscan2
- SLC13A1 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.914); catalogued as rs1442836162, COSV52007973, COSV52018264; called by muse, mutect2, varscan2
- SLC23A2 | c.790del p.E264Rfs*12 | Frame Shift Del (DEL) | VAF 10/103 reads (10%) | catalogued as COSV57777196; called by mutect2, pindel, varscan2
- SLC26A7 | c.677T>C p.V226A | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as rs753028751, COSV52596694; called by muse, mutect2, varscan2
- SLC45A4 | c.1483C>T p.R495C (on ENST00000517878 / NM_001286646.2; = p.R444C on NM_001080431.2) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV50144351; called by muse, mutect2
- SMARCAD1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs749813218, COSV62775038; called by muse, mutect2, varscan2
- SMG8 | c.51G>A p.W17* | Nonsense Mutation (SNP) | VAF 3/44 reads (7%) | catalogued as COSV56286009, COSV56286130; called by muse, mutect2
- SND1 | c.2110G>A p.G704S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs148285818; called by mutect2, varscan2
- SOAT2 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV56860421; called by muse, mutect2
- SOGA3 | c.722del p.G241Afs*133 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | catalogued as rs778091058, COSV100846885; called by mutect2, pindel, varscan2
- SOX2 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1207683228, COSV57622105; called by muse, mutect2, varscan2
- SPIDR | c.2065A>G p.R689G | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1322521056, COSV52381058; called by muse, mutect2
- SPOUT1 | c.354G>T p.E118D | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV100778206; called by muse, mutect2
- SPRR4 | c.50G>A p.R17K | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60142940; called by muse, mutect2
- SSH2 | c.784A>G p.M262V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52174961; called by muse, mutect2
- SSMEM1 | c.16del p.S6Pfs*6 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | catalogued as COSV52833923; called by mutect2, pindel
- STEAP3 | c.1228A>G p.T410A | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV61529652; called by muse, mutect2
- STXBP5 | c.1352T>G p.I451S | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV51654241; called by muse, mutect2, varscan2
- STYXL2 | c.2024C>T p.T675M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.374); catalogued as rs777654054, COSV54806750, COSV99068457; called by muse, mutect2, varscan2
- SUPT3H | c.621del p.A208Lfs*15 (on ENST00000371460 / NM_181356.3; = p.A197Lfs*15 on NM_003599.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | catalogued as rs1562126178, COSV60933976; called by mutect2, pindel, varscan2
- SUPT5H | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.241); catalogued as COSV63240586; called by muse, mutect2, varscan2
- SYNE1 | c.11414G>A p.R3805Q (on ENST00000367255 / NM_182961.4; = p.R3790Q on NM_033071.3) | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754270893, COSV54921171, COSV55010734; called by muse, mutect2, varscan2
- SYNJ2 | c.4058G>A p.S1353N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as rs1255067061, COSV62898433; called by muse, mutect2, varscan2
- TAF1B | c.1333A>T p.K445* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV55157336; called by muse, mutect2, varscan2
- TAFA3 | c.319del p.E107Rfs*41 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as COSV62624991; called by mutect2, pindel, varscan2
- TDRD9 | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1046701949, COSV59149797, COSV59152372; called by muse, mutect2
- TEAD2 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as rs957477299, COSV60544657, COSV60544723; called by muse, mutect2, varscan2
- TERF1 | c.1271G>T p.W424L (on ENST00000276603 / NM_017489.3; = p.W404L on NM_003218.4) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV52578459; called by muse, mutect2, varscan2
- TET3 | c.5027C>T p.T1676M | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV69641724; called by muse, mutect2, varscan2
- TEX10 | c.2617C>A p.L873I | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as COSV52444365; called by muse, mutect2
- TGM2 | c.1658A>T p.D553V | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as COSV63931816; called by muse, mutect2
- THSD7B | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV55704552; called by muse, mutect2, varscan2
- TLE2 | c.1663G>A p.V555I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs767088565, COSV53581008; called by muse, mutect2, varscan2
- TLN2 | c.3478G>A p.V1160M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs140997624; called by mutect2, varscan2
- TLR4 | c.1946T>G p.V649G (on ENST00000355622 / NM_138554.5; = p.V609G on NM_003266.4) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV62923647; called by muse, mutect2, varscan2
- TMEM255B | c.265A>T p.I89F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV64704235; called by muse, mutect2, varscan2
- TMEM26 | c.1016A>G p.Q339R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV53262732; called by muse, mutect2
- TMPRSS7 | c.1988T>C p.L663P (on ENST00000452346; = p.L537P on NM_001042575.2) | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69981364; called by muse, mutect2
- TMTC1 | c.1556C>T p.A519V (on ENST00000539277 / NM_001193451.2; = p.A411V on NM_175861.3) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs1359298899, COSV55479735; called by muse, mutect2
- TMTC4 | c.1774C>T p.R592C (on ENST00000376234 / NM_001350577.2; = p.R611C on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1430665035, COSV60891405; called by muse, mutect2, varscan2
- TNNT1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs201519507, COSV52572275; called by mutect2, varscan2
- TONSL | c.2618G>A p.R873H | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as rs982377750, COSV68048691; called by muse, varscan2
- TRIM2 | c.1582C>T p.R528C (on ENST00000437508; = p.R555C on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58635738; called by muse, mutect2, varscan2
- TRPM3 | c.2615C>T p.A872V (on ENST00000357533 / NM_001366142.2; = p.A715V on NM_020952.6) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV62588749; called by muse, mutect2
- TRPM4 | c.1397C>A p.A466E | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as COSV99419297; called by muse, mutect2, varscan2
- TSC2 | c.5234G>A p.R1745H | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766093661, COSV51919310; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TSPYL1 | c.368del p.K123Rfs*10 | Frame Shift Del (DEL) | VAF 10/93 reads (11%) | catalogued as COSV63994114; called by mutect2, pindel, varscan2
- TTK | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 15/179 reads (8%) | catalogued as COSV57884757; called by muse, mutect2
- TUBE1 | c.746del p.K249Sfs*10 | Frame Shift Del (DEL) | VAF 10/108 reads (9%) | catalogued as rs1554315980; called by mutect2, pindel
- TUSC3 | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65883460; called by muse, mutect2
- UBR4 | c.11002C>T p.P3668S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV64392545; called by muse, mutect2
- UBR4 | c.6484_6486del p.P2162del | In Frame Del (DEL) | VAF 11/114 reads (10%) | catalogued as rs757795486; called by mutect2, pindel
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 24/115 reads (21%) | catalogued as rs763652408; called by mutect2, varscan2
- UHRF1BP1 | c.2369T>C p.V790A | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV51957228; called by muse, mutect2
- UHRF1BP1L | c.1553C>A p.P518Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54439167; called by muse, mutect2
- USP28 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs554447859, COSV50168701; called by muse, mutect2, varscan2
- USP34 | c.7673G>A p.R2558H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV68401521; called by muse, mutect2, varscan2
- USP34 | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as rs142392366, COSV68398801; called by muse, mutect2, varscan2
- UTP14A | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV64087256; called by muse, mutect2, varscan2
- UTRN | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV62339509; called by muse, mutect2
- VPS13B | c.11620G>A p.V3874M | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781773703, COSV62147136; called by muse, varscan2
- VPS13C | c.10462G>T p.G3488C (on ENST00000644861 / NM_020821.3; = p.G3445C on NM_017684.5) | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51278322; called by muse, mutect2
- WDR7 | c.2467C>T p.R823C | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs745537548, COSV54352491; called by muse, mutect2, varscan2
- WFDC9 | c.28A>G p.M10V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV58097070; called by muse, mutect2, varscan2
- WWC2 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs755775249, COSV66714623; called by muse, mutect2, varscan2
- XKR9 | c.989T>C p.L330P | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs765019886, COSV68772810, COSV68773119; called by muse, mutect2, varscan2
- ZBTB40 | c.792dup p.L265Tfs*8 | Frame Shift Ins (INS) | VAF 12/96 reads (13%) | catalogued as rs775262758; called by mutect2, varscan2
- ZDHHC15 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as COSV64902515; called by muse, mutect2
- ZEB2 | c.2992A>G p.M998V | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.344); catalogued as COSV57959968; called by muse, mutect2
- ZFR | c.1960C>T p.R654C | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1433084139, COSV54054913; called by muse, mutect2
- ZHX1 | c.2116_2119del p.S706Gfs*14 | Frame Shift Del (DEL) | VAF 11/114 reads (10%) | catalogued as rs1482470201; called by pindel, varscan2
- ZNF106 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as COSV99782347; called by muse, mutect2, varscan2
- ZNF12 | c.1757_1759del p.F586del (on ENST00000405858 / NM_016265.4; = p.F548del on NM_006956.3) | In Frame Del (DEL) | VAF 4/44 reads (9%) | catalogued as rs1362915867; called by mutect2, pindel
- ZNF235 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs142725667; called by muse, mutect2, varscan2
- ZNF432 | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 13/143 reads (9%) | catalogued as rs74347014; called by muse, mutect2
- ZNF468 | c.1067C>T p.T356I | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as COSV54695449, COSV54696395; called by muse, mutect2
- ZNF486 | c.607del p.I203Lfs*28 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as rs1555718177; called by mutect2, pindel, varscan2
- ZNF496 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as COSV54178882; called by muse, mutect2
- ZNF556 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as rs146297141, COSV56911178; called by muse, mutect2, varscan2
- ZNF629 | c.2002G>A p.G668R | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52699313, COSV99354924; called by muse, mutect2
- ZNF862 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs748305753, COSV56222729; called by muse, varscan2
- ZSCAN31 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60181202; called by muse, mutect2
- ZYG11B | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.716); catalogued as COSV53754204; called by muse, mutect2
- ACACA | c.4877A>G p.Q1626R | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADAM29 | c.1641dup p.D548Rfs*10 | Frame Shift Ins (INS) | VAF 19/138 reads (14%) | called by mutect2, varscan2
- ADAM29 | c.1642delinsAT p.D548Ifs*10 | Frame Shift Ins (INS) | VAF 26/159 reads (16%) | called by mutect2*, pindel, varscan2*
- ADGRB3 | c.820del p.R274Gfs*57 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- ADNP | c.2062_2063insT p.R688Mfs*12 | Frame Shift Ins (INS) | VAF 12/97 reads (12%) | called by mutect2, pindel, varscan2
- AGO1 | c.1799del p.P600Qfs*14 | Frame Shift Del (DEL) | VAF 7/81 reads (9%) | called by mutect2, pindel
- AL592490.1 | c.810del p.Y271Tfs*2 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel, varscan2
- ARHGAP11A | c.375del p.F125Lfs*18 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, varscan2
- ARID1A | c.5693del p.P1898Hfs*25 | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | called by mutect2, varscan2
- ATRN | c.693del p.F231Lfs*8 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel, varscan2
- B4GALT3 | c.89del p.G30Afs*55 | Frame Shift Del (DEL) | VAF 9/92 reads (10%) | called by mutect2, varscan2
- CASD1 | c.2347del p.C783Vfs*21 | Frame Shift Del (DEL) | VAF 11/93 reads (12%) | called by mutect2, pindel, varscan2
- CBX2 | c.1014dup p.G339Wfs*74 | Frame Shift Ins (INS) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- CCT3 | c.591del p.K197Nfs*23 | Frame Shift Del (DEL) | VAF 18/188 reads (10%) | called by mutect2, pindel
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 8/90 reads (9%) | called by mutect2, pindel
- DEPDC1 | c.1091_1092del p.R364Tfs*14 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | called by pindel, varscan2
- DMXL1 | c.1229del p.L410Yfs*17 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel, varscan2
- ELF3 | c.1066A>G p.K356E | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2
- ERN2 | c.2340_2342del p.F781del | In Frame Del (DEL) | VAF 52/322 reads (16%) | called by pindel, varscan2
- FMNL3 | c.909dup p.E304* | Frame Shift Ins (INS) | VAF 11/102 reads (11%) | called by mutect2, pindel, varscan2
- GJA1 | c.450del p.L151Cfs*21 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | called by mutect2, pindel, varscan2
- GLIS2 | c.1026del p.D343Tfs*181 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- GPC4 | c.145del p.L49Sfs*9 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | called by mutect2, pindel, varscan2
- GPR141 | c.564del p.F188Lfs*3 | Frame Shift Del (DEL) | VAF 9/82 reads (11%) | called by mutect2, varscan2
- GRIA4 | c.519del p.A174Qfs*25 | Frame Shift Del (DEL) | VAF 10/101 reads (10%) | called by mutect2, pindel
- GTPBP1 | c.1593_1596del p.L532Afs*21 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- HOXA7 | c.265_266del p.I89Pfs*6 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- KANK2 | c.1636del p.Q546Sfs*45 (on ENST00000586659 / NM_001379562.1; = p.Q554Sfs*45 on NM_015493.7 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 14/101 reads (14%) | called by mutect2, pindel, varscan2
- KIF20B | c.3395del p.N1132Mfs*11 (on ENST00000371728 / NM_001284259.2; = p.N1092Mfs*11 on NM_016195.4) | Frame Shift Del (DEL) | VAF 12/91 reads (13%) | called by mutect2, pindel, varscan2
- LAMA2 | c.3272_3273del p.T1091Rfs*16 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel
- MACF1 | c.21092del p.K7031Sfs*6 (on ENST00000372915; = p.K5076Sfs*6 on NM_012090.5) | Frame Shift Del (DEL) | VAF 16/104 reads (15%) | called by mutect2, pindel, varscan2
- MCPH1 | c.12del p.I5Sfs*2 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- MTERF1 | c.1159del p.R387Dfs*6 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- MYO7B | c.767_769del p.Y256del | In Frame Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel, varscan2
- MYSM1 | c.102del p.D35Ifs*63 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- NEU2 | c.847del p.R283Afs*87 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel
- NUMA1 | c.2058del p.A687Qfs*25 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- PALMD | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PIP4K2B | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- PRAMEF14 | c.866+2T>C p.X289_splice | Splice Site (SNP) | VAF 25/173 reads (14%) | called by muse, mutect2, varscan2
- RAB11FIP2 | c.1101dup p.D368Rfs*2 | Frame Shift Ins (INS) | VAF 18/172 reads (10%) | called by mutect2, varscan2
- RAPGEF2 | c.1564del p.S522Vfs*12 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- RASIP1 | c.2740del p.L914Wfs*12 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel
- SLC38A9 | c.1289del p.L430* | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- SMAD2 | c.1206del p.F402Lfs*7 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.1914del p.A639Lfs*37 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- SYNE1 | c.2553del p.F851Lfs*9 (on ENST00000367255 / NM_182961.4; = p.F858Lfs*9 on NM_033071.3) | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- TAF1L | c.2784del p.F928Lfs*13 | Frame Shift Del (DEL) | VAF 14/157 reads (9%) | called by mutect2, pindel
- TBX5 | c.593del p.N198Ifs*15 | Frame Shift Del (DEL) | VAF 21/205 reads (10%) | called by mutect2, pindel, varscan2
- TJP1 | c.1950del p.F650Lfs*4 | Frame Shift Del (DEL) | VAF 21/127 reads (17%) | called by mutect2, pindel, varscan2
- TMEM236 | c.79A>G p.I27V | Missense Mutation (SNP) | VAF 36/482 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0.019); called by muse, mutect2
- TWF1 | c.408del p.K136Nfs*12 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- USH2A | c.14693del p.G4898Vfs*10 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- VWA7 | c.1260del p.K421Rfs*12 | Frame Shift Del (DEL) | VAF 7/70 reads (10%) | called by mutect2, pindel, varscan2
- YTHDF1 | c.362A>T p.N121I | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by mutect2, varscan2
- ZBED9 | c.3258del p.K1086Nfs*11 | Frame Shift Del (DEL) | VAF 11/89 reads (12%) | called by mutect2, pindel, varscan2
- ZC3H12B | c.2129_2130del p.Y710* | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- ZC3H7A | c.2632_2634del p.S878del | In Frame Del (DEL) | VAF 10/68 reads (15%) | called by pindel, varscan2
- ZNF605 | c.1206_1208del p.F403del | In Frame Del (DEL) | VAF 12/78 reads (15%) | called by pindel, varscan2
- ZNF668 | c.214dup p.E72Gfs*11 | Frame Shift Ins (INS) | VAF 6/71 reads (8%) | called by mutect2, pindel
- ACKR3 | c.198C>A p.V66= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99799416; called by muse, mutect2, varscan2
- ADAMTS10 | c.1641C>T p.D547= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV54354572; called by muse, mutect2, varscan2
- ADAMTS3 | c.363C>T p.T121= | Silent (SNP) | VAF 17/135 reads (13%) | catalogued as rs139575946, COSV54395052; called by muse, mutect2, varscan2
- ADCY7 | c.1026C>A p.T342= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- AFF1 | c.582A>G p.P194= | Silent (SNP) | VAF 15/129 reads (12%) | catalogued as COSV57121244; called by muse, mutect2, varscan2
- AKAP7 | c.796C>T p.L266= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV53835996; called by mutect2, varscan2
- AL669918.1 | c.2157C>T p.G719= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs370963057; called by muse, mutect2, varscan2
- ALDH4A1 | c.615G>A p.A205= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs766524857, COSV51889844; called by mutect2, varscan2
- APP | c.1407C>T p.R469= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV61000368; called by muse, mutect2
- ARFGAP3 | c.1443C>T p.N481= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as rs760218483, COSV54310530; called by muse, mutect2, varscan2
- BPIFB1 | c.222C>T p.G74= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV53607211; called by muse, mutect2, varscan2
- BRCA1 | c.1788C>T p.L596= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as rs779253414, COSV58793237; ClinVar: likely benign; called by muse, mutect2, varscan2
- C1QTNF4 | c.777C>T p.Y259= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV56783818; called by muse, mutect2
- C7orf31 | c.744C>T p.F248= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as rs139391560; called by muse, mutect2, varscan2
- C8G | c.525T>C p.T175= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV56403382; called by muse, mutect2, varscan2
- CCDC116 | c.1074T>C p.N358= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV53041152; called by muse, mutect2
- CCDC14 | c.2517T>C p.C839= (on ENST00000488653; = p.C791= on NM_022757.5) | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV59945688; called by muse, mutect2
- CCNJL | c.1137C>T p.H379= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as rs1171351861, COSV57445479; called by muse, mutect2
- CCR4 | c.222T>C p.T74= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV58382834; called by muse, mutect2
- CELSR3 | c.2157G>A p.V719= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV50894018; called by muse, mutect2
- CLIC1 | c.642C>T p.Y214= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs752246685, COSV101007584, COSV65384143; called by muse, mutect2, varscan2
- CLSTN3 | c.1281T>C p.L427= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV56937751; called by muse, mutect2
- CNP | c.252C>T p.D84= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs782683469, COSV66368497; called by muse, mutect2, varscan2
- COL6A6 | c.2709G>A p.R903= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV62029053; called by muse, mutect2
- DCAF12L2 | c.339C>T p.C113= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs779084575, COSV63582562; called by muse, mutect2, varscan2
- DDIT4 | c.84G>A p.R28= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV56577768; called by muse, mutect2
- DIPK1B | c.141C>T p.Y47= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs751892453, COSV65462446; called by mutect2, varscan2
- DNAJC14 | c.1803T>C p.A601= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV54478749; called by muse, mutect2, varscan2
- DOCK4 | c.4636C>T p.L1546= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV70239315; called by muse, varscan2
- DUS3L | c.1944G>A p.A648= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs772994460, COSV57832040; called by muse, mutect2
- DYSF | c.582G>A p.P194= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs779321489, COSV50458907; called by mutect2, varscan2
- EFCAB6 | c.3159G>A p.T1053= | Silent (SNP) | VAF 14/200 reads (7%) | catalogued as rs1419092876, COSV53066105; called by muse, mutect2
- EML1 | c.1146G>T p.T382= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as COSV51747481; called by muse, mutect2, varscan2
- EML5 | c.4980C>T p.C1660= (on ENST00000380664; = p.C1668= on NM_183387.3) | Silent (SNP) | VAF 6/85 reads (7%) | catalogued as rs1164578375, COSV61347611; called by muse, mutect2
- ERO1B | c.474T>C p.D158= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV59242850; called by muse, mutect2
- EXPH5 | c.2262C>T p.N754= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs775406227, COSV56199053; called by muse, mutect2, varscan2
- FAT4 | c.1893C>T p.S631= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs1246067040, COSV67890754; called by muse, mutect2, varscan2
- FBXO38 | c.2232G>A p.V744= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV57028998; called by muse, mutect2
- FOXK2 | c.183G>A p.S61= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV58880219; called by muse, mutect2
- GALNT15 | c.1470T>C p.A490= | Silent (SNP) | VAF 16/256 reads (6%) | catalogued as COSV60218082; called by muse, mutect2
- GRIP1 | c.1800C>T p.L600= (on ENST00000359742 / NM_001379345.1; = p.L548= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as rs750629778, COSV54029509; called by muse, mutect2
- HYI | c.570G>A p.T190= (on ENST00000372434 / NM_001330526.2; = p.T165= on NM_031207.6) | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs139460802; called by muse, mutect2, varscan2
- IFT172 | c.2493C>T p.C831= | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as COSV53135367; called by muse, mutect2, varscan2
- IKZF1 | c.1521G>A p.S507= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV58784808; called by muse, mutect2
- INTS5 | c.1392G>A p.P464= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as rs777523172, COSV57952184; called by muse, mutect2, varscan2
- ITGA8 | c.2802T>C p.C934= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV65231096; called by muse, mutect2
- ITGB6 | c.1329C>A p.A443= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99324279; called by muse, mutect2, varscan2
- KALRN | c.5991T>C p.C1997= (on ENST00000360013 / NM_001024660.4; = p.C300= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV52259147; called by muse, mutect2, varscan2
- KARS1 | c.1170C>T p.P390= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV56692991; called by muse, mutect2, varscan2
- KCNK6 | c.930C>T p.S310= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV54581022, COSV99649302; called by muse, mutect2
- KCNT1 | c.36C>T p.G12= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as rs1442852201, COSV53682685; called by muse, mutect2
- KDM3A | c.1590C>T p.F530= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs762222097, COSV57222471; called by muse, mutect2, varscan2
- KIRREL3 | c.942T>C p.C314= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV73106865; called by muse, mutect2
- KLHL14 | c.654C>T p.F218= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV63831706; called by muse, mutect2, varscan2
- KNDC1 | c.4359C>T p.C1453= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs970174179, COSV58840498; called by muse, mutect2, varscan2
- KRT4 | c.198T>C p.A66= | Silent (SNP) | VAF 16/189 reads (8%) | catalogued as COSV53408291; called by muse, mutect2
- KRTAP3-2 | c.216G>A p.Q72= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV66957166; called by muse, mutect2, varscan2
- LAMA4 | c.2520C>T p.G840= (on ENST00000230538 / NM_001105206.3; = p.G833= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV57899728; called by muse, mutect2
- LRCH4 | c.531A>G p.E177= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV53827197; called by muse, mutect2, varscan2
- MDGA2 | c.1779C>T p.N593= (on ENST00000399232 / NM_001113498.2; = p.N295= on NM_182830.4) | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as rs906373445, COSV62099551; called by muse, varscan2
- MPZL2 | c.216T>C p.P72= | Silent (SNP) | VAF 25/191 reads (13%) | catalogued as COSV54049088; called by muse, mutect2, varscan2
- MRPL2 | c.756T>C p.H252= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV54818924; called by muse, mutect2, varscan2
- MUC17 | c.3510G>A p.T1170= | Silent (SNP) | VAF 29/421 reads (7%) | catalogued as rs528164402, COSV60293236; called by muse, mutect2
- MYLK | c.849G>A p.S283= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs758274846, COSV100658655, COSV60613957; ClinVar: likely benign; called by mutect2, varscan2
- MYO15A | c.369C>T p.R123= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs555850466, COSV52752711; called by muse, mutect2, varscan2
- NAALADL2 | c.372C>T p.H124= | Silent (SNP) | VAF 13/149 reads (9%) | catalogued as rs993923083, COSV70795021; called by muse, mutect2
- NFAT5 | c.4032G>A p.S1344= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs900852295, COSV63029018; called by muse, mutect2, varscan2
- NT5M | c.648C>T p.D216= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs762190563, COSV101198560; called by muse, mutect2, varscan2
- NXN | c.444G>A p.R148= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV61097720; called by muse, mutect2, varscan2
- OPTN | c.1495C>T p.L499= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV53811585; called by muse, mutect2
- OR2A25 | c.435G>A p.L145= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as rs375258150; called by muse, mutect2, varscan2
- OR52D1 | c.867T>A p.P289= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs748602031, COSV59487796; called by muse, mutect2, varscan2
- OR5H2 | c.69A>G p.T23= | Silent (SNP) | VAF 36/274 reads (13%) | catalogued as COSV62351191; called by muse, mutect2, varscan2
- PCDHA2 | c.1827C>T p.Y609= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as rs375837956; called by muse, mutect2
- PCDHB1 | c.297C>T p.A99= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs782180084, COSV60631709; called by muse, mutect2, varscan2
- PCDHGA3 | c.2205G>A p.T735= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV53895291; called by muse, mutect2, varscan2
- PCYOX1 | c.1476T>C p.I492= | Silent (SNP) | VAF 21/156 reads (13%) | catalogued as COSV52476964; called by muse, mutect2, varscan2
- PDGFD | c.75G>A p.P25= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs769507921, COSV56382947; called by muse, mutect2, varscan2
- PLA2G3 | c.990G>A p.Q330= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as COSV53210593; called by muse, mutect2
- PLEKHG1 | c.1998T>C p.Y666= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV62048531; called by muse, mutect2
- PPARGC1B | c.2820C>T p.G940= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV58530681; called by muse, mutect2, varscan2
- PROCA1 | c.369C>A p.S123= (on ENST00000439862 / NM_001366301.1; = p.S95= on NM_152465.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/212 reads (8%) | catalogued as COSV56387310; called by muse, mutect2
- PRPF40A | c.1758T>C p.T586= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV62958623; called by muse, mutect2, varscan2
- RPP38 | c.324C>T p.H108= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs1326413090, COSV65382471; called by muse, mutect2, varscan2
- SKIV2L | c.2946C>T p.L982= | Silent (SNP) | VAF 10/111 reads (9%) | catalogued as rs776876478, COSV61714146; called by muse, mutect2
- SLC32A1 | c.1314G>A p.A438= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV54147281; called by muse, mutect2, varscan2
- SLC35G3 | c.387C>T p.N129= | Silent (SNP) | VAF 13/185 reads (7%) | catalogued as rs532177633, COSV52011759; called by muse, mutect2
- SLC6A5 | c.1281G>A p.T427= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs148416271, COSV54227609; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC8A1 | c.1545T>C p.V515= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV60486167; called by muse, mutect2, varscan2
- SLITRK5 | c.1353C>T p.R451= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs772460649, COSV61521812; called by muse, mutect2, varscan2
- SMAD2 | c.102T>C p.N34= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV51005784; called by muse, mutect2, varscan2
- SNAI3 | c.261C>A p.A87= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV100178799; called by muse, mutect2, varscan2
- SNX9 | c.279G>A p.S93= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs750073691, COSV67584887; called by muse, mutect2, varscan2
- SPTB | c.1407C>T p.T469= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs370960231, COSV67632902; called by muse, mutect2, varscan2
- SRP68 | c.1230G>A p.Q410= | Silent (SNP) | VAF 16/201 reads (8%) | catalogued as COSV57163314; called by muse, mutect2
- STAMBP | c.1026G>A p.A342= | Silent (SNP) | VAF 24/205 reads (12%) | catalogued as rs1319666970, COSV59897706; called by muse, mutect2, varscan2
- SYNE1 | c.26214C>T p.R8738= (on ENST00000367255 / NM_182961.4; = p.R8690= on NM_033071.3) | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as rs529628600, COSV54917214; ClinVar: likely benign; called by muse, mutect2, varscan2
- TEAD2 | c.1131G>A p.S377= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs375177887; called by muse, mutect2, varscan2
- THBD | c.1203G>A p.P401= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as rs1304888856, COSV65702723; called by muse, mutect2
- TLK2 | c.2283A>G p.S761= (on ENST00000326270 / NM_001284333.2; = p.S739= on NM_006852.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV58302036; called by muse, mutect2, varscan2
- TMCC2 | c.1596C>T p.H532= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as rs1475282116, COSV58004528; called by muse, mutect2
- TMEM130 | c.192C>T p.P64= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs782103844, COSV100228839, COSV59559859; called by muse, mutect2
- TNFSF4 | c.348C>T p.S116= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV56056880; called by muse, mutect2, varscan2
- TNP2 | c.228T>C p.S76= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV57129720; called by muse, mutect2
- TRAK1 | c.1941A>C p.P647= (on ENST00000327628 / NM_001349247.2; = p.P589= on NM_014965.5) | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV58260932, COSV58263749; called by muse, mutect2
- TRAPPC12 | c.873C>T p.D291= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs866676342, COSV60848818; called by muse, mutect2, varscan2
- TRBJ2-6 | c.33C>T p.A11= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs782355273; called by muse, mutect2, varscan2
- TRPC6 | c.387G>T p.V129= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV60256916; called by mutect2, varscan2
- USP37 | c.2872C>T p.L958= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV50290400; called by muse, mutect2
- WRN | c.618T>C p.T206= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV53302456; called by muse, mutect2
- ZBTB48 | c.684T>C p.S228= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV59840130; called by muse, mutect2
- ZNF19 | c.1296G>A p.E432= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs754425182, COSV55508014; called by muse, mutect2
- ZNF287 | c.1938A>G p.K646= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs201989061, COSV67688417, COSV67688609; called by mutect2, varscan2
- ZNF467 | c.741G>A p.A247= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs768301215, COSV57372579; called by muse, mutect2
- ZNF48 | c.1524A>G p.P508= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV60783586; called by muse, mutect2, varscan2
- ZNF770 | c.1677A>G p.Q559= | Silent (SNP) | VAF 30/179 reads (17%) | catalogued as rs1409971759, COSV62544482; called by muse, mutect2, varscan2
- ZNF792 | c.1878C>A p.T626= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV101289682; called by muse, mutect2
- ACAD9 | c.*118G>A | 3'UTR (SNP) | VAF 6/50 reads (12%) | catalogued as rs773593776, COSV100459025; called by muse, mutect2
- AL590867.2 | n.427del | RNA (DEL) | VAF 7/45 reads (16%) | catalogued as rs747858319; called by mutect2, pindel, varscan2
- ASIC2 | c.556-179421C>T | Intron (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99859589; called by muse, mutect2
- CBX1 | c.*1C>T | 3'UTR (SNP) | VAF 6/41 reads (15%) | catalogued as rs759971221, COSV56682004; called by mutect2, varscan2
- CD300LB | c.-64A>G | 5'UTR (SNP) | VAF 6/48 reads (13%) | catalogued as COSV58725918; called by muse, mutect2, varscan2
- CPLANE1 | chr5:37169113 G>A | 3'Flank (SNP) | VAF 8/90 reads (9%) | catalogued as COSV57064808; called by muse, mutect2
- DST | c.4297-2698T>G | Intron (SNP) | VAF 12/120 reads (10%) | catalogued as COSV99752903; called by muse, mutect2
- FLCN | c.871+43C>T | Intron (SNP) | VAF 8/55 reads (15%) | catalogued as rs1353479689, COSV53261068; called by muse, mutect2, varscan2
- GLIPR1L2 | c.670+30del | Intron (DEL) | VAF 8/68 reads (12%) | catalogued as rs769479789; called by mutect2, pindel
- KLHL7 | c.121-5867_121-5865del | Intron (DEL) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- MGAM | c.4618+1224C>T | Intron (SNP) | VAF 12/166 reads (7%) | catalogued as rs531387144, COSV72075045; called by muse, mutect2
- TMEM183B | n.1014C>T | RNA (SNP) | VAF 16/251 reads (6%) | called by muse, mutect2
- TTN | c.10361-4806C>T | Intron (SNP) | VAF 8/97 reads (8%) | catalogued as rs1486807945, COSV60154178; called by muse, mutect2
